Gene-level copy-number profile of tumor specimen AP-KX5B-VY from APOLLO case AP-KX5B, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen AP-KX5B-VY: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f61decb8-adfc-4de5-b121-c9526df66127.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-KX5B-DA (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/f1e07648-a509-46db-9a3f-fc92d6687a56

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 244; copy number 1: 6,088; copy number 2: 16,138; copy number 3: 24,407; copy number 4: 9,766; copy number 5: 2,247; copy number 7: 11.

Homozygous deletions (total copy number 0; autosomes only): 230 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,601,418–38,783,108, 8 genes: ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr10:131,772,398–133,778,699, 80 genes (broad region; genes not listed).
- chr15:19,878,555–22,686,213, 138 genes (broad region; genes not listed).
- chr20:30,484,925–30,816,274, 4 genes: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:29,795,938–29,983,114, 5 genes, copy number 7: AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1.
- chr19:58,559,129–58,605,223, 6 genes, copy number 7: MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.

Autosomal genes at a single copy (total copy number 1): 4,786. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
